Somatic mutation profile of tumor specimen MP2PRT-PASNPT-TMP1-A (aliquot MP2PRT-PASNPT-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASNPT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,749 days).
Specimen MP2PRT-PASNPT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 214e4453-bc81-4eff-9bc3-6766d0951a34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASNPT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASNPT-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e8ebe77-c2ce-42f3-bb1d-e2849c116e30

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 112/300 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775708192, COSV52927509; called by muse, mutect2, varscan2
- WDFY4 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 255/462 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416225271; called by muse, mutect2, varscan2
- CREBBP | c.5104C>T p.R1702C | Missense Mutation (SNP) | VAF 183/463 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM162B | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 112/409 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MARCHF11 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCGF1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- WDR74 | c.209_210insGC p.F70Lfs*59 | Frame Shift Ins (INS) | VAF 126/353 reads (36%) | called by mutect2, pindel*, varscan2*
- KCNG1 | c.1194C>T p.I398= | Silent (SNP) | VAF 178/395 reads (45%) | catalogued as COSV65369599; called by muse, mutect2, varscan2
- MSLN | c.1014C>T p.R338= | Silent (SNP) | VAF 162/387 reads (42%) | catalogued as rs541447705; called by muse, mutect2, varscan2
- SLC13A1 | c.537C>T p.H179= | Silent (SNP) | VAF 69/200 reads (35%) | catalogued as rs766450646, COSV52008059; called by muse, mutect2, varscan2
